TCGA case TCGA-AJ-A3BF — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: International Genomics Conosrtium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/40287cdc-19dd-4370-a6a0-f324960e1148

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (3)
1. Papillary serous cystadenocarcinoma (the primary disease): ICD-O-3 morphology code: 8460/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,906 days); Year of diagnosis: 2011; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IIIC2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 551 days (1.5 years).
   Pathology details: Consistent pathology review: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 2; Lymph nodes tested: 43.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 6; Lymph nodes tested: 14.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 75 days; Days to treatment end: 251 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 136 days; Days to treatment end: 176 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 411 days (1.1 years); Days to treatment end: 457 days (1.3 years); Treatment dose: 5,940 cGy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 517 days (1.4 years); Days to treatment end: 551 days (1.5 years); Treatment dose: 5,500 cGy; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Papillary serous cystadenocarcinoma), site: Intra-abdominal lymph nodes. Age at diagnosis: 66.5 years (24,290 days); Days to diagnosis: 384 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Papillary serous cystadenocarcinoma), site: Lymph nodes of axilla or arm. Age at diagnosis: 66.8 years (24,415 days); Days to diagnosis: 509 days (1.4 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 34 days; Disease response: Tumor Free.
- Day 384 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 384 days (1.1 years).
- Day 509 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of axilla or arm; Days to progression: 509 days (1.4 years).
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.
- Follow-up contact recording only the day: day 551.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Menopause status: Postmenopausal; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 170 cm; BMI: 39.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AJ-A3BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-AJ-A3BF-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AJ-A3BF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AJ-A3BF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Surgical approach at diagnosis: open; Lymph nodes pelvic pos by IHC: 0; Lymph nodes aortic pos by IHC: 0.
- Follow-up form 1: Lost to follow-up: No; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 551 days; disease-specific survival: no event (censored), 551 days; disease-free interval: event (new tumor event after initially disease-free), 384 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 384 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AJ-A3BF-01A-11D-A20R-01): tumor purity 0.8, ploidy 1.88, whole-genome doublings 0.
